Surgical pathology report (de-identified scan), TCGA case TCGA-VD-A8KI, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-A8KI-01A (Primary Tumor).

[page 1 of 2]
Department of Pathology

Page 1 of 4

REPORT Tel:

Clinical Consultant & Location

Sex

Unit No

This Copy For:

SPECIMEN

Right eye (enucleation)

CLINICAL DETAILS

Right choroidal melanoma.
See diagram.

MACROSCOPIC DESCRIPTION

An intact right eye.

Dimensions: Axial 24mm, Horizontal 24mm, Vertical 23mm

Cornea: Horizontal 12mm, Vertical 12mm

Optic nerve
Length 9mm, Diameter 4mm

Pupil: normal, regular

On description, on infero postero is a dark pigmented nodule
??? 6mm x 4mm height (3mm from optic nerve).

On trans-illumination, there is a dark shadow in ? side of
the globe - 22 x 21mm and developed in the optic nerve
insertion.

Plane of section: vertical

Intraocular description:

On sectioning a dome shaped pigmented choroidal mass
measuring LBD 15mm, height 12mm.

Tumour size

LBD 15mm, Height 12mm

MICROSCOPY

Histologically, the enucleated eye demonstrates a normal
anterior segment with an unremarkable cornea, a deep
anterior chamber and open angles. The iris leaves are
unremarkable. The ciliary muscles are moderately atrophic.

Reported:

Pathologist:

Electronically Verified:

ICD O-3
Melanoma epithelioid & spindle
cell mixed 8770/3
Site B Choroid C69.3
JGD 11/17/14

[page 2 of 2]
Department of Pathology

Page 2 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

There is mild hyalinisation of the ciliary processes. The lens shows moderately advanced cataractous changes.

In the posterior segment, at the level of the equator, a choroidal melanoma can be seen. This is dome-shaped with a large accompanying exudative retinal detachment. The retina overlying the tumour is atrophic with degenerative changes, and focally there is retinal invasion.

The tumour is partially pigmented and consists of a mixture of cells, both epithelioid and spindle cells, with a slight dominance of the latter. The epithelioid cell component is approx. 40%. The melanoma cells are immunoreactive for MelanA, SOX-10 and HSP-27 (score 2).

The number of mitoses is approx. 5/40 high power fields. The microvasculature of the melanoma is prominent, but closed loops are not present in the tissue planes evaluated. Occasional "vascular lakes" can be observed; in these tumour cells can be seen located within the lumen. The lymphocytic infiltrate within tumour is minimal. Macrophages are scattered throughout the tumour in moderate density.

There is a large extraocular growth, which has arisen at two sites, transclerally. These are 3mm and 1mm in diameter, respectively. The larger is encapsulated only by a very thin layer of connective tissue.

The optic nerve is tumour free, and demonstrates mild atrophic changes. The examined vortex veins are free of tumour.

DIAGNOSIS

Choroidal melanoma of mixed cell type with extraocular melanoma growth.

COMMENT

Molecular genetic examination of DNA extracted from the tumour cells will be performed using multiplex-ligation dependent probe amplification (MLPA), looking at chromosomes

Reported:

Pathologist:

Electronically Verified:

Source: NCI Genomic Data Commons file 325664bd-02de-4227-b984-864ac76f9efe (TCGA-VD-A8KI.7F74C718-5BFD-466A-B03F-B61B587D92EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).